Surgical pathology report (de-identified scan), TCGA case TCGA-GN-A9SD, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Roswell, specimen TCGA-GN-A9SD-06A (Metastatic).

[page 1 of 2]
Surg Date

SPECIMENS:

- A. RIGHT GROIN SUPERFICIAL LYMPH NODE
- B. RIGHT EXTERNAL ILIAC LYMPH NODE
- C. ADDITIONAL RIGHT EXTERNAL ILIAC LYMPH NODE
- D. RIGHT OBTURATOR LYMPH NODE
- E. ADDITIONAL PREPERITONEAL TISSUE

SPECIMEN(S):

- A. RIGHT GROIN SUPERFICIAL LYMPH NODE
- B. RIGHT EXTERNAL ILIAC LYMPH NODE
- C. ADDITIONAL RIGHT EXTERNAL ILIAC LYMPH NODE
- D. RIGHT OBTURATOR LYMPH NODE
- E. ADDITIONAL PREPERITONEAL TISSUE

DIAGNOSIS:

- A. LYMPH NODE, RIGHT GROIN SUPERFICIAL, EXCISION:
- THREE OF SEVEN LYMPH NODES POSITIVE FOR METASTATIC MELANOMA, MACROMETASTASIS WITH EXTRANODAL EXTENSION. (3/7)
- ASSOCIATED FIBRO-VASCULAR TISSUE IS NEGATIVE FOR METASTATIC MELANOMA.
- B. LYMPH NODE, RIGHT, EXTERNAL ILIAC, EXCISION:
- ONE LYMPH NODE POSITIVE FOR METASTATIC MELANOMA, MACROMETASTASIS WITH EXTRANODAL EXTENSION. (1/1)
- C. LYMPH NODE, RIGHT, ADDITIONAL EXTERNAL ILIAC, EXCISION:
- TWO LYMPH NODES NEGATIVE FOR METASTASIS. (0/2)
- MINUTE FOCUS OF ENDOSAPINGIOSIS.
- D. LYMPH NODE, RIGHT OBTURATOR, EXCISION:
- ONE OF FIVE LYMPH NODES POSITIVE FOR METASTATIC MELANOMA, MICROMETASTASIS WITH EXTRANODAL EXTENSION. (1/5)
- E. SOFT TISSUE, ADDITIONAL PRE-PERITONEAL TISSUE, BIOPSY:
- ONE LYMPH NODE, AND ASSOCIATED FIBRO-DIPOSE TISSUE NEGATIVE FOR METASTASIS. (0/1)

GROSS DESCRIPTION:

A. RIGHT GROIN SUPERFICIAL LYMPH NODE

Received fresh labeled with the patient's identification and "right groin superficial lymph node" is an unoriented piece of yellow-tan soft tissue, 45 x 10.5 x 3 cm. On sectioning, are multiple blood vessels with lumens up to 0.2 cm and areas of dense fibrous tissue with embedded staples and sutures. The lymph nodes ranging from 1.2 x 1.2 x 0.6 cm to 2.4 x 2.2 x 1.1 cm. Lymph nodes are sectioned and have variegated pink and black-tan cut surfaces admixed with fat and fibrous tissue; lymph nodes are submitted entirely:

A1: blood vessels

A2: fibrous tissue

A3-A6: 1 sectioned lymph node in each cassette

A7-A9: 1 sectioned lymph node

A 10-A11: 1 bisected lymph node

A12-A13: 1 bisected lymph node

B. RIGHT EXTERNAL ILIAC LYMPH NODE

Received fresh labeled with the patient's identification and designated "right external iliac lymph node" is a red-tan lymph node with attached adipose tissue measuring 3.9 x 2.8 x 2.9 cm. The specimen is sectioned to show dark brown/gray, soft, fleshy cut surface. A portion of the specimen is submitted for tissue procurement. Representative sections are submitted, B1-B2.

C. ADDITIONAL RIGHT EXTERNAL ILIAC LYMPH NODE

Received in formalin labeled with the patient's identification and designated "additional right iliac lymph node" are multiple fragments of red-tan soft tissue measuring 3.9 x 2.8 x 0.4 cm in aggregate.

ICD-03

Melanoma NOS 8720/3

Date lymph node, groin 77.4

JW 3/11/14

[page 2 of 2]
Surg Date

Sectioning shows two possible lymph nodes, 1.9 x 1.4 x 0.4 cm and 3.5 x 0.9 x 0.4 cm. The entire specimen is submitted:

C1: One bisected lymph node

C2: One bisected lymph node

C3: Remainder of the specimen

D. RIGHT OBTURATOR LYMPH NODE

Received in formalin labeled with the patient's identification and designated "right obturator lymph node" is a portion of red-tan soft tissue measuring 5.8 x 4.5 x 1.1 cm. Sectioning shows multiple possible lymph nodes ranging from 0.2 x 0.2 x 0.2 up to 4.3 x 3.5 x 1.1 cm. Cassettes are submitted as follows:

D1: 4 possible lymph nodes

D2-D7: One lymph node, sectioned

E. ADDITIONAL PRE-PERITONEAL TISSUE

Received in formalin labeled with the patient's identification and designated "additional preperitoneal tissue" are two fragments of red-tan soft tissue measuring 1.5 x 1.4 x 0.3 cm in aggregate. Entirely submitted, E1.

CLINICAL HISTORY:

None Given

PRE-OPERATIVE DIAGNOSIS:

None Given

ADDENDUM:

Addendum is issued to report the immunohistochemical studies in the table below. The original diagnosis remains unchanged.

SUMMARY OF IMMUNOHISTOCHEMISTRY/SPECIAL STAINS

Material: Block A5

Population: Lymph Node

Stain/Marker:Result: Comment:

HMB 45 Negative

A103,MELAN-A Negative

The interpretation of the above immunohistochemistry stain or stains is guided by published results in the medical literature, provided package information from the manufacturer and by internal review of staining performance and assay validation within the Immunohistochemistry Laboratory. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristic determined by the Department of Pathology Laboratory. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Special stains and/or immunohistochemical stains were performed with appropriately stained positive and/or negative controls.

Gross Dictation: M.D., Pathologist,
Microscopic/Diagnostic Dictation: M.D., Pathologist
Final Review: M.D., Pathologist
Final Review: M.D., Pathologist
Microscopic/Diagnostic Dictation:
Final Review: M.D., Pathologist
Final: M.D., Pathologist
Addendum: M.D., Pathologist
Addendum Final: M.D., Pathologist

Source: NCI Genomic Data Commons file 3561a2a8-a3c6-401c-811d-4ce4cb7e7cb5 (TCGA-GN-A9SD.5DB9F1BC-9654-4F38-90E4-2F93237E357C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).